Somatic mutation profile of tumor specimen TCGA-D3-A8GB-06A (aliquot TCGA-D3-A8GB-06A-11D-A372-08) from TCGA case TCGA-D3-A8GB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 49.0 years (17,905 days).
Specimen TCGA-D3-A8GB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2786127-ce6d-457a-a994-3beaeb088cb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GB-10A (Blood Derived Normal), aliquot TCGA-D3-A8GB-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/002dea57-3ed5-4779-ae8c-d78bb4816c6d

The open-access MAF lists 1,251 somatic variants for this specimen: 795 protein-altering or splice-affecting, 427 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 709, Silent 427, Nonsense Mutation 56, Splice Site 12, Intron 12, Splice Region 11, RNA 6, Translation Start Site 4, 3'Flank 3, 3'UTR 3, Frame Shift Del 3, 5'UTR 3.

Variants (750 of 1,251; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DNAH17 | c.3766G>A p.G1256R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs768564744, COSV101101399; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TECTA | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as rs764424917, COSV50693039; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100206859; called by muse, mutect2, varscan2
- AASDHPPT | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99593415; called by muse, mutect2, varscan2
- ABCA2 | c.2646C>T p.S882= (on ENST00000614293; = p.S852= on NM_001606.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 10/85 reads (12%) | catalogued as rs776393568, COSV99687747; called by muse, mutect2, varscan2
- ABCC11 | c.3394C>T p.P1132S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as rs769721654, COSV100751044; called by muse, mutect2, varscan2
- ABCC6 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); catalogued as COSV52742735; called by muse, mutect2, varscan2
- ACACB | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV100623232; called by muse, mutect2, varscan2
- ACBD4 | c.611G>A p.G204E (on ENST00000376955 / NM_001378111.1; = p.R207= on NM_024722.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100416299; called by muse, mutect2, varscan2
- ACSS2 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53622649, COSV99490176; called by muse, mutect2
- ACSS2 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99490180; called by muse, mutect2
- ADAM19 | c.1942T>G p.F648V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.61); catalogued as rs1479651474, COSV99978273; called by muse, mutect2, varscan2
- ADAM7 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51541613; called by muse, mutect2, varscan2
- ADAMTS16 | c.3008G>A p.G1003E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99941969; called by muse, mutect2, varscan2
- ADAMTS18 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99273944; called by muse, mutect2, varscan2
- ADAMTS2 | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs979855168, COSV52365317; called by muse, mutect2, varscan2
- ADAMTS20 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867354506, COSV67132676; called by muse, mutect2, varscan2
- ADGRA2 | c.2546C>G p.T849R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99605094; called by muse, mutect2, varscan2
- ADGRE1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs767902336, COSV51675820; called by muse, mutect2
- ADH1C | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV101565201; called by muse, mutect2, varscan2
- ADH4 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV99644368; called by muse, mutect2, varscan2
- ADORA2B | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as rs780014133, COSV100420057; called by muse, mutect2, varscan2
- AGAP1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs754181254, COSV100366917; called by muse, mutect2, varscan2
- AGAP6 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs148430930, COSV65017376; called by muse, mutect2, varscan2
- AHDC1 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV99899689; called by muse, mutect2, varscan2
- AK5 | c.712G>A p.D238N (on ENST00000354567 / NM_174858.3; = p.D212N on NM_012093.4) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1019747082, COSV60982163; called by muse, mutect2, varscan2
- AKR1A1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs147072115; called by muse, mutect2, varscan2
- AMBP | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99468983; called by muse, mutect2, varscan2
- AMY2B | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 40/381 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100796471, COSV63716137; called by muse, mutect2, varscan2
- ANGPTL1 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.426); catalogued as rs746052727, COSV52367292; called by muse, mutect2, varscan2
- ANK3 | c.3409G>A p.V1137I (on ENST00000280772 / NM_001320874.2; = p.V271I on NM_001149.3) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs142899762; called by muse, mutect2, varscan2
- ANKRD13A | c.1703G>A p.W568* | Nonsense Mutation (SNP) | VAF 10/105 reads (10%) | catalogued as COSV99924108; called by muse, mutect2
- ANKRD30A | c.3885G>A p.M1295I (on ENST00000611781; = p.M1239I on NM_052997.2) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64619968; called by muse, varscan2
- ANKRD30A | c.3895G>A p.E1299K (on ENST00000611781; = p.E1243K on NM_052997.2) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100654322; called by muse, varscan2
- ANO1 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as rs372809100, COSV60289022; called by muse, mutect2
- ANTXR1 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.215); catalogued as COSV100362985; called by muse, mutect2
- ANXA11 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as rs1318489141, COSV55417492; called by muse, mutect2, varscan2
- APBB2 | c.1022C>T p.S341F (on ENST00000295974 / NM_001166050.2; = p.S342F on NM_004307.2) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as rs1168526873, COSV99923973; called by muse, mutect2, varscan2
- APOB | c.12247G>A p.D4083N | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as rs762211836, COSV99267553; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.8356G>A p.E2786K | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs373774326; called by muse, mutect2, varscan2
- APOB | c.5632G>A p.A1878T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV99267558; called by muse, mutect2, varscan2
- APOBR | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV100112879; called by muse, mutect2
- AQP6 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100210268; called by muse, mutect2
- ARAP3 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.523); catalogued as rs1489163108, COSV99499908, COSV99500214; called by muse, mutect2, varscan2
- ARFGAP2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 80/489 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV100096561; called by muse, mutect2, varscan2
- ARFGAP3 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs1224583354, COSV99605521; called by muse, mutect2, varscan2
- ARHGAP10 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV100331697; called by muse, mutect2, varscan2
- ARHGAP17 | c.1736C>T p.P579L (on ENST00000289968 / NM_001006634.3; = p.P501L on NM_018054.6) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs755242883, COSV51508922; called by muse, mutect2, varscan2
- ARHGAP30 | c.2987C>T p.S996F (on ENST00000368013 / NM_001025598.2; = p.S785F on NM_181720.3) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1364684862, COSV100920474; called by muse, mutect2, varscan2
- ARHGAP35 | c.2767C>T p.P923S | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as COSV101351501, COSV101351576; called by muse, mutect2, varscan2
- ARHGEF17 | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99736613; called by muse, mutect2
- ARHGEF5 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99283144; called by mutect2, varscan2
- ARID4B | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99936221; called by muse, mutect2
- ARMCX3 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV100362325; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.56); PolyPhen probably damaging (1); catalogued as COSV63437218; called by muse, mutect2, varscan2
- ARPP21 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV51792463, COSV99491948; called by muse, mutect2, varscan2
- ASB5 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99642039; called by muse, mutect2, varscan2
- ASS1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100752805; called by muse, mutect2, varscan2
- ASTN1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV99922842; called by muse, mutect2
- ASXL3 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99326248; called by muse, mutect2, varscan2
- ATG9B | c.2093del p.R698Lfs*11 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as COSV52495112, COSV99871984; called by mutect2, varscan2
- ATP13A5 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149839711, COSV60868943; called by muse, mutect2, varscan2
- ATRIP | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.925); catalogued as rs775618032, COSV100202940; called by muse, mutect2, varscan2
- B3GNT4 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1186567182, COSV99928355; called by muse, mutect2, varscan2
- B3GNT4 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779055570, COSV57338115; called by mutect2, varscan2
- B4GALNT2 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs756612045, COSV55924974; called by muse, mutect2, varscan2
- BACH1 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV99728634; called by muse, mutect2, varscan2
- BAG6 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 22/212 reads (10%) | catalogued as rs1180421542, COSV99277541; called by muse, mutect2, varscan2
- BNIP5 | c.729G>A p.Q243= | Splice Region (SNP) | VAF 36/228 reads (16%) | catalogued as COSV101465208; called by muse, mutect2, varscan2
- BNIP5 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV101465209; called by muse, mutect2, varscan2
- BSN | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99609624; called by muse, mutect2, varscan2
- BTBD8 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); catalogued as COSV61546128; called by muse, mutect2, varscan2
- BTN1A1 | c.884G>A p.W295* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | catalogued as rs756211134, COSV99764530; called by muse, mutect2, varscan2
- C16orf82 | c.1C>T p.M1? | Translation Start Site (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760338549; called by muse, mutect2, varscan2
- C1orf158 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs368618094; called by muse, mutect2, varscan2
- C2orf16 | c.2312G>A p.G771E | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as COSV100820965; called by muse, mutect2, varscan2
- C2orf80 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58017695; called by muse, mutect2, varscan2
- C5 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99798585; called by muse, mutect2, varscan2
- C9orf24 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.845); catalogued as rs756694663, COSV52623922; called by muse, mutect2, varscan2
- CACHD1 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs757326006, COSV99263155; called by muse, mutect2, varscan2
- CACNA1E | c.3251C>T p.T1084I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as rs1200821009, COSV100704860; called by muse, mutect2
- CACNA1H | c.5095G>A p.E1699K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100673383; called by muse, mutect2, varscan2
- CACNA1H | c.6395T>G p.L2132R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV99327046; called by muse, mutect2
- CACNA1S | c.4856C>T p.P1619L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV100755329; called by muse, mutect2, varscan2
- CALN1 | c.277G>A p.D93N (on ENST00000329008 / NM_001017440.3; = p.D135N on NM_031468.4) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV61142880, COSV61151370; called by muse, mutect2, varscan2
- CAMK1D | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs763942938, COSV66608333; called by muse, mutect2, varscan2
- CAMTA1 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.202); catalogued as rs1472780033, COSV100352196; called by muse, mutect2, varscan2
- CARMIL2 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1379998885, COSV100576229; called by muse, mutect2, varscan2
- CASKIN2 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV100050855; called by muse, mutect2, varscan2
- CATSPER4 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs762569758, COSV58793888; called by muse, mutect2, varscan2
- CATSPERD | c.2261G>A p.R754K | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as rs777755788, COSV100486957; called by muse, mutect2
- CCDC102B | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs1291563604, COSV100104726; called by muse, mutect2, varscan2
- CCDC112 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | catalogued as COSV101100465, COSV101100515; called by muse, mutect2, varscan2
- CCDC149 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs200140047, COSV100164850; called by muse, mutect2, varscan2
- CCDC181 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100890381; called by muse, mutect2, varscan2
- CCDC39 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV56481424; called by muse, mutect2, varscan2
- CCDC54 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV99660316; called by muse, mutect2, varscan2
- CCDC60 | c.1330A>T p.K444* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100555613; called by muse, mutect2, varscan2
- CCDC88A | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV99711087; called by muse, mutect2, varscan2
- CCS | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs763126852, COSV100040142; called by muse, mutect2
- CD163 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63130859; called by muse, mutect2, varscan2
- CD1C | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 81/474 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs759928678, COSV63805662; called by muse, mutect2, varscan2
- CD200R1L | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101236544, COSV101236633; called by muse, mutect2, varscan2
- CD36 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.124); catalogued as COSV99987829; called by muse, mutect2, varscan2
- CD6 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as COSV57836671; called by muse, mutect2
- CD63 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV57676384; called by muse, mutect2, varscan2
- CD7 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs769841402, COSV99486366; called by muse, mutect2, varscan2
- CDH10 | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as COSV52577289; called by muse, mutect2, varscan2
- CDH4 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100849488; called by muse, mutect2, varscan2
- CDH4 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64650740; called by muse, mutect2, varscan2
- CDH5 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58518096; called by muse, mutect2, varscan2
- CDKL4 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV101115501; called by muse, mutect2, varscan2
- CECR2 | c.2567C>T p.S856F (on ENST00000342247 / NM_001290047.2; = p.S673F on NM_001290046.1) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV99378962; called by muse, mutect2, varscan2
- CELF4 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV100611952; called by muse, mutect2
- CEP128 | c.2194C>T p.H732Y | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs527705008, COSV55379545; called by muse, mutect2, varscan2
- CFAP206 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405987812, COSV65806689; called by muse, mutect2
- CFAP46 | c.7108G>A p.E2370K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV99585456; called by muse, mutect2, varscan2
- CFHR3 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as rs1460615140, COSV66401464; called by muse, mutect2, varscan2
- CHD1L | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); catalogued as COSV63614980; called by muse, mutect2
- CHD1L | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV100787575; called by muse, mutect2
- CHD2 | c.2935C>T p.L979F | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101245899; called by muse, mutect2, varscan2
- CHD7 | c.6523G>A p.V2175M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as rs1563661076, COSV101418400; called by muse, mutect2
- CHRM1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.287); catalogued as rs767451271, COSV100186290; called by muse, mutect2, varscan2
- CHRNA2 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs1381205264, COSV99532468; called by muse, mutect2
- CHRNB3 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs1163299616, COSV99251433; called by muse, mutect2, varscan2
- CHST15 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV100655220, COSV100655333; called by muse, mutect2, varscan2
- CIAPIN1 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1158384696, COSV101275921; called by muse, mutect2, varscan2
- CLCA4 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV55366472; called by muse, mutect2
- CLEC4D | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs1162892581, COSV55227904, COSV55228313; called by muse, mutect2, varscan2
- CLEC4G | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100183717; called by muse, mutect2, varscan2
- CLEC6A | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs938570101, COSV65986832; called by muse, mutect2, varscan2
- CLIP2 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99792150; called by muse, mutect2, varscan2
- CNGB3 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369526115, COSV60693835; called by muse, mutect2, varscan2
- CNNM2 | c.2233G>A p.G745S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV100881919; called by muse, mutect2, varscan2
- CNTN4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018920181, COSV61867465; called by muse, mutect2, varscan2
- COL1A2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1253543311; called by muse, mutect2
- COL6A2 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1263106677, COSV99385404; called by muse, mutect2, varscan2
- COL6A3 | c.4816G>A p.E1606K | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.239); catalogued as COSV55080376, COSV99800871; called by muse, mutect2, varscan2
- COL9A2 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101025768, COSV65607345; called by muse, mutect2, varscan2
- COX7C | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99915244; called by muse, mutect2, varscan2
- CPA1 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782112003, CM139174, COSV99163343, COSV99163384; called by muse, mutect2, varscan2
- CPA1 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99163344; called by muse, mutect2, varscan2
- CPA3 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936426; called by muse, mutect2, varscan2
- CPAMD8 | c.3220G>A p.A1074T (on ENST00000651564; = p.A1027T on NM_015692.5) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV101488576; called by muse, mutect2, varscan2
- CPED1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100121411; called by muse, mutect2, varscan2
- CPLANE1 | c.*2605G>A | Splice Region (SNP) | VAF 10/66 reads (15%) | catalogued as COSV57069724; called by muse, mutect2, varscan2
- CRACDL | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1370787325, COSV101194133; called by muse, mutect2, varscan2
- CRB1 | c.2512A>T p.K838* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as CM155700, COSV100958059; called by muse, mutect2, varscan2
- CRIM1 | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99754317; called by muse, mutect2, varscan2
- CRIM1 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs773047364, COSV99754319; called by muse, mutect2, varscan2
- CRISPLD2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99295990; called by muse, mutect2, varscan2
- CRNN | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV99664335; called by muse, mutect2, varscan2
- CSE1L | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773304297, COSV53705084; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100989947; called by muse, mutect2, varscan2
- CSMD1 | c.3892C>T p.P1298S (on ENST00000520002; = p.P1297S on NM_033225.6) | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59347314, COSV59352439; called by muse, mutect2, varscan2
- CSMD3 | c.5068C>T p.H1690Y (on ENST00000297405 / NM_001363185.1; = p.H1586Y on NM_052900.3) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.792); catalogued as rs267601732, COSV52138124; called by muse, mutect2, varscan2
- CTCFL | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 54/395 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV99713224; called by muse, mutect2, varscan2
- CTDP1 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50003537; called by muse, mutect2, varscan2
- CTNNA2 | c.2293C>T p.Q765* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as rs1216751050, COSV100559967, COSV100561884; called by muse, mutect2
- CUBN | c.10219A>G p.R3407G | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV100913418; called by muse, mutect2, varscan2
- CXCR2 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100579106; called by muse, mutect2, varscan2
- CYP11A1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV51432897; called by muse, mutect2
- CYP27A1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99298720; called by muse, mutect2
- CYP2S1 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as COSV100027581; called by muse, mutect2, varscan2
- CYP4A11 | c.1364+1G>A p.X455_splice | Splice Site (SNP) | VAF 44/336 reads (13%) | catalogued as rs1211676821, COSV100152603; called by muse, mutect2, varscan2
- DAB2IP | c.2212C>T p.Q738* (on ENST00000408936; = p.Q710* on NM_032552.3) | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52270681; called by muse, mutect2, varscan2
- DBF4B | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV100154420; called by muse, mutect2
- DCDC1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs781437821, COSV60836779, COSV60849362; called by muse, mutect2, varscan2
- DCDC2 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.037); catalogued as COSV101015519, COSV65829438; called by muse, mutect2, varscan2
- DDI1 | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.538); catalogued as COSV100160603, COSV56384519; called by muse, mutect2
- DDX3X | c.1553C>T p.P518L (on ENST00000399959; = p.P519L on NM_001356.5) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101302508; called by muse, mutect2, varscan2
- DDX56 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs1392585288, COSV99346228; called by muse, mutect2, varscan2
- DHX34 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV60894998; called by muse, mutect2, varscan2
- DIO1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100498983; called by muse, mutect2, varscan2
- DIP2A | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100596278; called by muse, mutect2
- DISC1 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99698497; called by muse, mutect2
- DKC1 | c.1310T>C p.V437A | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV101054009; called by muse, mutect2, varscan2
- DLG5 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100967122; called by muse, mutect2
- DLGAP3 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.26); catalogued as COSV99331991; called by mutect2, varscan2
- DMC1 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319457; called by muse, mutect2, varscan2
- DMXL1 | c.6124C>T p.R2042C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs750727596, COSV100224396; called by muse, mutect2, varscan2
- DNAH10 | c.12785G>A p.G4262D (on ENST00000409039; = p.G4201D on NM_207437.3) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV99435867; called by muse, mutect2, varscan2
- DNAH11 | c.11616G>A p.W3872* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as rs765087313, COSV100180548; called by mutect2, varscan2
- DNAH7 | c.10204A>T p.I3402F | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100417151; called by muse, mutect2, varscan2
- DNAH7 | c.9467C>T p.S3156L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100415915; called by muse, mutect2, varscan2
- DNAH7 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100417154; called by muse, mutect2, varscan2
- DNAH8 | c.4097C>T p.S1366F | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV100546958; called by muse, mutect2, varscan2
- DNAJA2 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV57695359; called by muse, mutect2, varscan2
- DNAJB8 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs758063580, COSV100048467; called by muse, mutect2, varscan2
- DOCK5 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99377705; called by muse, mutect2, varscan2
- DONSON | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99281152; called by muse, mutect2, varscan2
- DPP6 | c.433G>A p.D145N (on ENST00000377770 / NM_001364500.2; = p.D83N on NM_001936.5) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV100127789, COSV59613685, COSV59642779; called by muse, mutect2, varscan2
- DQX1 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99283761; called by muse, mutect2, varscan2
- DQX1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs1266398325, COSV101099195; called by muse, mutect2, varscan2
- DSG3 | c.1930G>A p.G644R | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV99934651; called by muse, mutect2, varscan2
- DST | c.9703C>T p.L3235F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.037); catalogued as COSV99759362; called by muse, mutect2, varscan2
- DTNB | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV99977948; called by muse, mutect2, varscan2
- DYNLRB2 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1277468318, COSV100009830; called by muse, mutect2, varscan2
- DZIP3 | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100848029, COSV64314069; called by muse, mutect2, varscan2
- EDA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1358758982, COSV100999570, COSV65776782; called by muse, mutect2, varscan2
- EDA | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV101000157; called by muse, mutect2, varscan2
- EEF1A1 | c.1131A>T p.E377D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); catalogued as COSV100303415; called by muse, mutect2, varscan2
- EEF1A2 | c.560C>G p.T187S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.014); catalogued as COSV99419819; called by muse, mutect2, varscan2
- EEF1E1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1303274828, COSV65675779; called by muse, mutect2, varscan2
- EFL1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51609908; called by muse, mutect2
- EGFR | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV51776578; called by muse, mutect2, varscan2
- EIF2B1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99967654; called by muse, mutect2, varscan2
- EIF4G1 | c.943C>T p.P315S (on ENST00000346169 / NM_198241.3; = p.P119S on NM_004953.5) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100072243; called by muse, mutect2, varscan2
- ELAVL1 | c.791T>G p.F264C | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688489; called by muse, mutect2, varscan2
- ELOA2 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as COSV99797780; called by muse, mutect2, varscan2
- EPHA1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV51977051; called by muse, mutect2, varscan2
- EPHA7 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV100994253; called by mutect2, varscan2
- ERBB4 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751175543, COSV53515716; called by muse, mutect2, varscan2
- ERMARD | c.712A>T p.T238S | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV100824906; called by muse, mutect2, varscan2
- ESRRG | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs1430921691, COSV100753778; called by muse, mutect2, varscan2
- ETFDH | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as CM166213, COSV100310088; called by muse, mutect2
- ETNPPL | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.178); catalogued as COSV99625608; called by muse, mutect2, varscan2
- ETNPPL | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99625615; called by muse, mutect2, varscan2
- EZR | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.219); catalogued as COSV99792506; called by muse, mutect2, varscan2
- FAM151B | c.65A>T p.N22I | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99971869; called by muse, mutect2
- FAM209A | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.876); catalogued as COSV99711696; called by muse, mutect2, varscan2
- FAM214A | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99958454; called by muse, mutect2, varscan2
- FAM221B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65073698; called by muse, mutect2, varscan2
- FAM47B | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV61455522; called by muse, mutect2, varscan2
- FAM50B | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as rs1279967084, COSV100976604; called by muse, mutect2, varscan2
- FARS2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99213171; called by mutect2, varscan2
- FAT2 | c.4279C>T p.R1427C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs779294736; called by muse, mutect2, varscan2
- FAT3 | c.10808G>A p.G3603E | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99970337; called by muse, mutect2, varscan2
- FBH1 | c.760C>T p.P254S (on ENST00000362091 / NM_178150.3; = p.P305S on NM_032807.4) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62983068; called by muse, mutect2, varscan2
- FBH1 | c.761C>T p.P254L (on ENST00000362091 / NM_178150.3; = p.P305L on NM_032807.4) | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100758914; called by muse, mutect2, varscan2
- FBN3 | c.4693G>A p.D1565N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs767659218, COSV54457780; called by mutect2, varscan2
- FBXL12 | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99928115; called by muse, mutect2, varscan2
- FBXO40 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs373304473; called by muse, mutect2, varscan2
- FBXW10 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV100111712, COSV57320579; called by muse, mutect2
- FCAR | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV62028522; called by muse, mutect2, varscan2
- FCRL5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.013); catalogued as rs1406891065, COSV62512447, COSV62513927; called by muse, mutect2, varscan2
- FGF23 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99426669; called by muse, mutect2, varscan2
- FLT1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56718941, COSV99164999, COSV99166035; called by muse, mutect2, varscan2
- FMNL1 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.18); catalogued as COSV100056882; called by muse, mutect2, varscan2
- FMO2 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99269316; called by muse, mutect2, varscan2
- FMO2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs144453031; called by muse, mutect2, varscan2
- FNIP2 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs758552637, COSV100033236; called by mutect2, varscan2
- FOLH1 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99923828; called by muse, mutect2, varscan2
- FOXL1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs750763910, COSV100206391; called by muse, mutect2
- FOXP3 | c.1142G>A p.W381* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs1557115586, COSV100873248; called by muse, mutect2, varscan2
- FRMD3 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.749); catalogued as COSV100171051; called by muse, mutect2, varscan2
- FRMPD1 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs559954392, COSV100899619; called by muse, mutect2, varscan2
- FRMPD2 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs747020741, COSV100564126; called by muse, mutect2, varscan2
- FUT5 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99398967; called by muse, mutect2, varscan2
- FYB1 | c.2293G>A p.D765N (on ENST00000351578 / NM_199335.5; = p.D811N on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV100686222; called by muse, mutect2, varscan2
- FYB2 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV58584329, COSV58587681; called by muse, mutect2, varscan2
- GABRA2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100734447, COSV100734861; called by muse, mutect2, varscan2
- GABRA6 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379529914, COSV99194958; called by muse, mutect2, varscan2
- GABRA6 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50878989, COSV50879242; called by muse, mutect2, varscan2
- GALNS | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM124268, COSV51939672, COSV99243415; called by muse, mutect2, varscan2
- GCNA | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV101032670; called by mutect2, varscan2
- GDPD1 | c.367+1G>A p.X123_splice | Splice Site (SNP) | VAF 18/139 reads (13%) | catalogued as COSV99405306; called by muse, mutect2, varscan2
- GEN1 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1335562971, COSV100438169; called by muse, mutect2, varscan2
- GFRAL | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV61229588; called by muse, mutect2, varscan2
- GJB7 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99738677; called by muse, mutect2, varscan2
- GJC1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 21/172 reads (12%) | catalogued as COSV100395225; called by muse, mutect2, varscan2
- GLIPR1L2 | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1315443961, COSV100248758; called by muse, mutect2, varscan2
- GLRA1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99199674; called by muse, mutect2, varscan2
- GLYATL2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99780521; called by muse, mutect2
- GOLGB1 | c.9566C>A p.S3189Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100101060; called by muse, mutect2, varscan2
- GPHN | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as COSV100017531; called by muse, mutect2
- GPR176 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100137482; called by muse, mutect2, varscan2
- GPRC5C | c.1195C>T p.P399S (on ENST00000652232; = p.P354S on NM_018653.4) | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as COSV100702986; called by muse, mutect2
- GRIK3 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.049); catalogued as rs1186035598, COSV66135421; called by muse, mutect2, varscan2
- GRIN2A | c.2714C>T p.S905F | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV58035058; called by muse, mutect2, varscan2
- GRIN2A | c.1116G>A p.W372* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as rs1555501090, COSV100410857; called by muse, mutect2, varscan2
- GRM3 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467226; called by muse, mutect2, varscan2
- GRM6 | c.2602C>T p.P868S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs937277106, COSV99179865; called by muse, mutect2, varscan2
- GTF3C2 | c.1297C>T p.H433Y | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99273230; called by muse, mutect2, varscan2
- GTSE1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV101483251; called by muse, mutect2, varscan2
- GTSE1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV101483252; called by muse, mutect2, varscan2
- H3C10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV60797298, COSV60799019; called by muse, mutect2, varscan2
- HCRTR2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs766006062, COSV63793711, COSV99057010; called by muse, mutect2, varscan2
- HDAC7 | c.1247C>T p.P416L (on ENST00000427332; = p.P455L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs114936068; called by muse, mutect2, varscan2
- HDAC7 | c.1246C>T p.P416S (on ENST00000427332; = p.P455S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99316850; called by muse, mutect2, varscan2
- HECTD4 | c.7192G>A p.G2398S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101108326; called by muse, mutect2
- HECW1 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101224206; called by muse, mutect2, varscan2
- HHATL | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs765197293, COSV55132823; called by muse, mutect2, varscan2
- HMGB4 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV53914788; called by muse, mutect2, varscan2
- HMGCLL1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV51441581; called by muse, mutect2, varscan2
- HNF4A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs748452860, COSV57382487; called by muse, mutect2, varscan2
- HOMER2 | c.647C>T p.S216F (on ENST00000304231 / NM_199330.3; = p.S205F on NM_004839.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV58484765; called by muse, mutect2, varscan2
- HOXA3 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV100415661; called by muse, mutect2, varscan2
- HOXB13 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV99285340; called by muse, mutect2, varscan2
- HRC | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99418275; called by muse, mutect2, varscan2
- HSPA4L | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV99613609; called by muse, mutect2
- HTR3C | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.764); catalogued as COSV100570735; called by muse, mutect2, varscan2
- HTR3C | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100570736; called by muse, mutect2, varscan2
- HUNK | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs141493785; called by muse, mutect2, varscan2
- HUWE1 | c.8417C>T p.P2806L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV99473972; called by muse, mutect2, varscan2
- HYDIN | c.10144C>T p.R3382C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376896772, COSV101158183; called by muse, mutect2, varscan2
- IGKJ4 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | PolyPhen possibly damaging (0.784); catalogued as rs753061589; called by muse, mutect2, varscan2
- IGSF10 | c.7024C>T p.P2342S | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99176580, COSV99193374; called by muse, mutect2, varscan2
- IHH | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99838784; called by muse, mutect2, varscan2
- IL18 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199505901, COSV54780968; called by muse, mutect2, varscan2
- IL2RA | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as COSV56923049; called by muse, mutect2, varscan2
- ILDR1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99878916; called by muse, mutect2
- INSYN2A | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs1450672394, COSV99732240; called by muse, mutect2, varscan2
- IPP | c.1501C>T p.H501Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100739694; called by muse, mutect2, varscan2
- IQGAP2 | c.736T>A p.L246I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV99167920; called by muse, mutect2, varscan2
- IRF2BPL | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); catalogued as COSV99468440; called by muse, mutect2
- ITGA10 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781934718, COSV100995029; called by muse, mutect2
- ITGA7 | c.3388G>A p.E1130K (on ENST00000555728; = p.E1086K on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV57695695; called by muse, mutect2, varscan2
- ITGAX | c.3476C>T p.P1159L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199778020; called by muse, mutect2
- ITSN2 | c.2082G>A p.R694= | Splice Region (SNP) | VAF 4/19 reads (21%) | catalogued as rs774551081, COSV61945824; called by muse, mutect2
- JCAD | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.273); catalogued as rs1564444502, COSV100948541; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV100584186; called by muse, mutect2, varscan2
- KALRN | c.5533A>T p.I1845F (on ENST00000360013 / NM_001024660.4; = p.I148F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99362800; called by mutect2, varscan2
- KANK3 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100445140; called by muse, mutect2, varscan2
- KAT2A | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99863683; called by muse, mutect2, varscan2
- KBTBD3 | c.1302G>A p.W434* | Nonsense Mutation (SNP) | VAF 15/138 reads (11%) | catalogued as COSV101595722; called by muse, mutect2, varscan2
- KCNA4 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068715; called by muse, mutect2, varscan2
- KCNB2 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.912); catalogued as COSV101578972; called by muse, mutect2, varscan2
- KCNG4 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs971081303, COSV100377156; called by muse, mutect2, varscan2
- KCNH3 | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99235697; called by muse, mutect2, varscan2
- KCNH4 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99236944, COSV99237799; called by muse, mutect2, varscan2
- KCNK10 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV100069160; called by muse, mutect2, varscan2
- KDM4B | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99347245; called by muse, mutect2
- KDM6B | c.3478C>T p.L1160F | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs201793001, COSV99642175; called by muse, mutect2, varscan2
- KIAA1217 | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419486067, COSV56819435; called by muse, mutect2, varscan2
- KIF21B | c.2650C>T p.H884Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV100145042; called by muse, mutect2, varscan2
- KIF2A | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1340819916, COSV101136653; called by muse, mutect2, varscan2
- KLHDC7B | c.1550C>T p.S517F (on ENST00000395676; = p.S1158F on NM_138433.5) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.165); catalogued as rs769127729, COSV101192976; called by muse, mutect2, varscan2
- KLHL13 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1314523330, COSV53245217; called by muse, mutect2, varscan2
- KLK15 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334556379, COSV56826981; called by muse, mutect2, varscan2
- KLRK1 | c.278-1G>A p.X93_splice | Splice Site (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99555237; called by muse, mutect2, varscan2
- KRT1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.527); catalogued as rs761610111, COSV99358968; called by muse, mutect2, varscan2
- KRT1 | c.466A>T p.T156S | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.739); catalogued as COSV99358969; called by muse, mutect2, varscan2
- KRT28 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as COSV100137630; called by muse, mutect2, varscan2
- KRT3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs751579090, COSV58814476; called by muse, mutect2, varscan2
- KRT75 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV99359610; called by muse, mutect2, varscan2
- KRTAP10-5 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100555282; called by muse, varscan2
- KRTAP5-10 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.624); catalogued as rs1420272308, COSV100924136, COSV100924150; called by muse, mutect2
- KSR2 | c.1367G>A p.C456Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100196522; called by muse, mutect2, varscan2
- L3MBTL2 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.105); catalogued as COSV99346128; called by muse, mutect2, varscan2
- LALBA | c.368+1G>A p.X123_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | catalogued as COSV56395342, COSV56396637, COSV99974472; called by muse, varscan2
- LALBA | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99974475; called by muse, mutect2, varscan2
- LAMA2 | c.4256C>T p.P1419L | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV101370781; called by muse, mutect2, varscan2
- LAMB4 | c.4474G>A p.E1492K | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV52718714; called by muse, mutect2
- LHCGR | c.328A>G p.N110D | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV54299271, COSV99684142; called by muse, mutect2, varscan2
- LILRA1 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs992108041, COSV52186417; called by muse, mutect2
- LILRB1 | c.656C>T p.S219F (on ENST00000427581; = p.S183F on NM_006669.6) | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV61116350; called by muse, varscan2
- LIN37 | c.588C>T p.P196= | Splice Region (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99137503; called by muse, mutect2
- LIN9 | c.1333-1G>A p.X445_splice (on ENST00000366808 / NM_001270410.2; = p.X390_splice on NM_173083.3 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100067925; called by muse, mutect2, varscan2
- LNX1 | c.666A>T p.K222N (on ENST00000263925 / NM_001126328.3; = p.K126N on NM_032622.2) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV99820510; called by muse, mutect2
- LPAR1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62690909; called by mutect2, varscan2
- LPO | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs776560852, COSV51862684; called by muse, mutect2, varscan2
- LRP10 | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); catalogued as COSV100612485; called by muse, mutect2, varscan2
- LRP1B | c.4499G>A p.G1500E | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67284556; called by muse, mutect2, varscan2
- LRP1B | c.3799C>T p.R1267C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1219622803, COSV67184580; called by muse, mutect2
- LRP2 | c.12188G>A p.R4063Q | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as rs773743636, COSV99789996; called by muse, mutect2, varscan2
- LRP2 | c.12053C>T p.P4018L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV55548702; called by muse, mutect2
- LRP6 | c.4508G>A p.G1503E | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.732); catalogued as COSV99744312; called by muse, mutect2, varscan2
- LRRC15 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV100752905; called by muse, mutect2, varscan2
- LRRC46 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV99274302; called by muse, mutect2, varscan2
- LRRIQ1 | c.336G>A p.K112= | Splice Region (SNP) | VAF 8/82 reads (10%) | catalogued as COSV101277719, COSV101277737; called by muse, mutect2
- LRRIQ3 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1236814969, COSV100599361; called by muse, mutect2, varscan2
- LTBP1 | c.2311C>T p.P771S (on ENST00000404816 / NM_206943.4; = p.P445S on NM_000627.4) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100617885; called by muse, mutect2, varscan2
- LUM | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99899180; called by muse, mutect2, varscan2
- LVRN | c.979-1G>A p.X327_splice | Splice Site (SNP) | VAF 17/92 reads (18%) | catalogued as COSV100773657; called by muse, varscan2
- LVRN | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV100773658; called by muse, varscan2
- LYN | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101319633; called by muse, mutect2, varscan2
- MACF1 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as rs770636733, COSV100482988, COSV100486155; called by muse, mutect2, varscan2
- MACF1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100486156; called by muse, mutect2, varscan2
- MAGEC1 | c.2855A>T p.K952I | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99596407; called by muse, mutect2, varscan2
- MAP3K19 | c.1370A>G p.E457G | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100209141; called by muse, mutect2, varscan2
- MAP3K19 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100209146; called by muse, mutect2, varscan2
- MAP4K1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1267299952, COSV67708703, COSV67711656; called by muse, mutect2, varscan2
- MAP7 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100644010; called by muse, mutect2, varscan2
- MARK1 | c.1843C>T p.H615Y | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100857523; called by muse, mutect2, varscan2
- MASP2 | c.1873G>A p.G625S | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99534436; called by muse, mutect2, varscan2
- MAZ | c.1280-1G>A p.X427_splice | Splice Site (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99361445; called by muse, mutect2, varscan2
- MCHR2 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV56009879, COSV99912209; called by muse, mutect2, varscan2
- MCM3 | c.1036C>T p.R346C (on ENST00000229854 / NM_001366374.2; = p.R336C on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57718307; called by muse, mutect2, varscan2
- MCMBP | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139316442; called by muse, mutect2, varscan2
- MDFI | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV57822353; called by muse, mutect2, varscan2
- MDGA2 | c.2693G>A p.G898E (on ENST00000399232 / NM_001113498.2; = p.G600E on NM_182830.4) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV62086382; called by muse, mutect2, varscan2
- MECOM | c.1537C>T p.P513S (on ENST00000468789 / NM_001105078.4; = p.P701S on NM_004991.4) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99245247; called by muse, mutect2, varscan2
- MFSD1 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs1473718343, COSV99963806, COSV99964045; called by muse, mutect2, varscan2
- MGAM | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72073904; called by muse, mutect2, varscan2
- MIP | c.360+1G>A p.X120_splice | Splice Site (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99234397; called by muse, mutect2, varscan2
- MMP1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100188077; called by muse, mutect2, varscan2
- MMP10 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1435227921, COSV99666562; called by muse, mutect2
- MMP19 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 31/194 reads (16%) | catalogued as rs758525325, COSV100491249; called by muse, mutect2, varscan2
- MMP21 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100916692; called by muse, mutect2, varscan2
- MMP24 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750265403, COSV99864087; called by muse, mutect2, varscan2
- MMP3 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55405598; called by muse, mutect2
- MMUT | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs776065390, COSV99222542; called by muse, mutect2, varscan2
- MORC1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.76); catalogued as COSV99227578; called by muse, mutect2, varscan2
- MORC1 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV99227579; called by muse, mutect2
- MOV10 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as rs369968810; called by muse, mutect2, varscan2
- MROH2B | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs377423987; called by muse, mutect2, varscan2
- MROH2B | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.135); catalogued as rs760329436, COSV101270894; called by muse, mutect2, varscan2
- MRPL37 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as rs766984304, COSV99839160; called by muse, mutect2, varscan2
- MTA1 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100495449; called by muse, mutect2
- MTCL1 | c.1288G>T p.D430Y (on ENST00000306329 / NM_001378206.1; = p.D70Y on NM_015210.4) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100095452; called by muse, mutect2, varscan2
- MTNR1A | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV100208314; called by muse, mutect2, varscan2
- MUC16 | c.20297C>T p.S6766L | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs200769888; called by muse, mutect2, varscan2
- MUC6 | c.6328C>A p.Q2110K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1453182750, COSV101424770; called by muse, mutect2, varscan2
- MUC6 | c.5207C>T p.S1736F | Missense Mutation (SNP) | VAF 42/1075 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as rs534774807, COSV101424772; called by muse, mutect2
- MYEOV | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 50/756 reads (7%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.019); catalogued as COSV100456727; called by muse, mutect2
- MYH7 | c.5563G>A p.E1855K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV62521010; called by muse, mutect2
- MYLK3 | c.1986-1G>A p.X662_splice | Splice Site (SNP) | VAF 4/57 reads (7%) | catalogued as COSV101189193; called by muse, mutect2
- MYO15A | c.7117G>A p.E2373K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV99234237; called by muse, mutect2
- MYO15A | c.7117+1G>A p.X2373_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | catalogued as COSV99234238; called by muse, mutect2
- MYO9A | c.6028C>T p.P2010S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs1470435070, COSV61857750; called by muse, mutect2, varscan2
- MYOCD | c.105C>G p.N35K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100591312; called by muse, mutect2, varscan2
- MYOCD | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1394360964, COSV58497819; called by muse, mutect2, varscan2
- NAAA | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs199653966, COSV54432425; called by muse, mutect2, varscan2
- NAIP | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); catalogued as rs200427852, COSV99519437; called by muse, mutect2
- NARF | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV59114322; called by muse, mutect2, varscan2
- NBEA | c.8095G>A p.D2699N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100083605; called by muse, mutect2
- NCAN | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV53049997, COSV99387729; called by muse, mutect2, varscan2
- NCKAP5 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100494123; called by muse, mutect2, varscan2
- NCOR1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs778810900, COSV51977615; called by muse, mutect2, varscan2
- NFASC | c.1024G>A p.E342K (on ENST00000339876 / NM_001378329.1; = p.E353K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs1395051180, COSV58379240; called by muse, mutect2, varscan2
- NFRKB | c.3869C>T p.P1290L (on ENST00000446488 / NM_001143835.2; = p.P1315L on NM_006165.3) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs759553565, COSV99859418, COSV99859550; called by muse, mutect2, varscan2
- NIPBL | c.5331C>T p.I1777= | Splice Region (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99242344; called by muse, mutect2, varscan2
- NLGN4Y | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV52970062; called by muse, mutect2, varscan2
- NLRP2 | c.2880-1G>A p.X960_splice | Splice Site (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99672001; called by muse, mutect2, varscan2
- NLRP4 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.241); catalogued as COSV100017017; called by muse, mutect2, varscan2
- NLRP4 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs868450451, COSV56715942; called by muse, mutect2, varscan2
- NPR1 | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1259710099, COSV100902071; called by muse, mutect2, varscan2
- NR3C2 | c.199A>C p.K67Q | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.726); catalogued as COSV100679685; called by muse, mutect2, varscan2
- NRXN3 | c.2150G>A p.R717Q (on ENST00000335750 / NM_001330195.2; = p.R344Q on NM_004796.6) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59733958; called by muse, mutect2, varscan2
- NRXN3 | c.3163G>A p.E1055K (on ENST00000335750 / NM_001330195.2; = p.E682K on NM_004796.6) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59794308; called by muse, mutect2
- NSMCE2 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99787323; called by muse, mutect2, varscan2
- NTRK3 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV100447888; called by muse, mutect2, varscan2
- NUBP1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1206823476, COSV99296944; called by muse, mutect2, varscan2
- NUGGC | c.1631G>A p.G544D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV100429721; called by muse, mutect2
- NWD1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV100343560; called by muse, mutect2, varscan2
- NYAP2 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.43); PolyPhen probably damaging (1); catalogued as COSV99798234; called by muse, mutect2, varscan2
- NYAP2 | c.1283G>A p.G428D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99798238; called by muse, mutect2, varscan2
- OBSCN | c.15326C>T p.P5109L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99483483; called by muse, mutect2, varscan2
- OBSL1 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99217401; called by muse, mutect2, varscan2
- OGDHL | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227541536, COSV100934495; called by muse, mutect2, varscan2
- OPRPN | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs186164636, COSV68193268; called by muse, mutect2, varscan2
- OR10A4 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.053); catalogued as COSV101139585; called by muse, mutect2, varscan2
- OR10A6 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100564346; called by muse, mutect2, varscan2
- OR10H1 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100612483, COSV58473295; called by muse, mutect2, varscan2
- OR2C3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs200581250, COSV63574834; called by muse, mutect2, varscan2
- OR2M2 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs539993597, COSV100677310; called by muse, mutect2, varscan2
- OR2M3 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 60/367 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71759068; called by muse, mutect2, varscan2
- OR4A5 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.295); catalogued as rs770249402, COSV60521838; called by mutect2, varscan2
- OR4C16 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs778549908, COSV58940741; called by muse, mutect2, varscan2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR4D6 | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as rs756119521, COSV100271821; called by muse, mutect2
- OR4K5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV60003041; called by muse, mutect2, varscan2
- OR51D1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs747448893; called by muse, mutect2, varscan2
- OR51S1 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100437578; called by muse, mutect2, varscan2
- OR52E8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/113 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV66205992; called by muse, mutect2, varscan2
- OR52L1 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.615); catalogued as COSV100176307; called by muse, mutect2, varscan2
- OR5H6 | c.95G>A p.G32E (on ENST00000642105; = p.G16E on NM_001005479.2) | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765251519, COSV67351343; called by muse, mutect2, varscan2
- OR6B1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 21/171 reads (12%) | catalogued as rs745433880, COSV68770009; called by muse, varscan2
- OR6B1 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs752940401, COSV68769870, COSV68770350; called by muse, varscan2
- OR6S1 | c.542T>G p.F181C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100289501; called by muse, mutect2, varscan2
- OR8H2 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV57944518; called by muse, mutect2, varscan2
- OR8H2 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs747942374, COSV100542462; called by muse, mutect2, varscan2
- ORAI2 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV62689321, COSV62689340; called by muse, mutect2
- ORM2 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as COSV99800960; called by muse, mutect2, varscan2
- OTOA | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV99625652; called by muse, mutect2, varscan2
- P2RX2 | c.1475A>C p.K492T (on ENST00000343948 / NM_170683.4; = p.K394T on NM_012226.5) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV100267997; called by muse, mutect2, varscan2
- PADI2 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as COSV100971072; called by muse, mutect2, varscan2
- PAGE5 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs1199659556, COSV99215838; called by muse, mutect2
- PAPPA | c.3188C>T p.S1063F | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); catalogued as COSV60278038, COSV60279223, COSV60287666; called by muse, mutect2
- PBLD | c.193T>A p.F65I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99516211; called by muse, mutect2, varscan2
- PC | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 237/360 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100540875; called by muse, mutect2, varscan2
- PCDH15 | c.4619C>T p.S1540L | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV57260063; called by muse, mutect2, varscan2
- PCDHA2 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65370281; called by muse, mutect2, varscan2
- PCDHA4 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV100793706; called by muse, mutect2, varscan2
- PCDHB11 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1474246664, COSV99504933; called by muse, mutect2, varscan2
- PCDHB12 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53394680; called by muse, mutect2, varscan2
- PCDHB8 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1423776247, COSV99177024; called by muse, mutect2
- PCDHGA2 | c.2310C>A p.F770L | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV53969375, COSV99545694; called by muse, mutect2, varscan2
- PCK1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs139902878; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCLO | c.10033G>A p.E3345K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV100436896; called by muse, mutect2, varscan2
- PCLO | c.7406G>T p.R2469I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); catalogued as rs756646613, COSV100436903; called by muse, mutect2, varscan2
- PCLO | c.5963G>A p.G1988E | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV61646298; called by muse, mutect2
- PCLO | c.3686C>T p.S1229F | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100436908; called by muse, mutect2, varscan2
- PCSK1 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100227249; called by muse, mutect2, varscan2
- PDE3B | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99963159; called by muse, mutect2, varscan2
- PDE6A | c.717+2T>C p.X239_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99678648; called by muse, mutect2
- PDE8B | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99367476; called by muse, mutect2, varscan2
- PDHA2 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV54780038; called by muse, mutect2, varscan2
- PDIA4 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53723525; called by muse, mutect2, varscan2
- PHF20 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as COSV59184910; called by muse, mutect2, varscan2
- PHKG2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100079800; called by muse, mutect2, varscan2
- PIEZO2 | c.7498G>A p.E2500K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.047); catalogued as COSV53288088; called by muse, mutect2, varscan2
- PIK3AP1 | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV59532752; called by muse, mutect2, varscan2
- PIK3AP1 | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100226160; called by muse, mutect2, varscan2
- PINX1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs750637295, COSV100135007; called by muse, mutect2, varscan2
- PITPNM1 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as rs1450669429, COSV100711726; called by muse, mutect2
- PLAG1 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as rs780434899, COSV100388179; called by muse, mutect2, varscan2
- PLCG2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100842594; called by muse, mutect2, varscan2
- PLEKHG1 | c.682T>A p.F228I | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100651845; called by muse, mutect2, varscan2
- PLEKHG4B | c.1026G>A p.W342* (on ENST00000283426; = p.W698* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99360955; called by muse, mutect2, varscan2
- PLXNB3 | c.4544C>T p.P1515L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1557063969, COSV100737830; called by muse, mutect2
- PM20D2 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99248492; called by muse, mutect2, varscan2
- PM20D2 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383038868, COSV99248499; called by muse, mutect2, varscan2
- PNPLA5 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1239897281, COSV53376466; called by muse, mutect2
- PNPLA6 | c.2967G>A p.R989= (on ENST00000414982 / NM_001166111.2; = p.R941= on NM_006702.5) | Splice Region (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99654414; called by muse, mutect2, varscan2
- PODXL | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100539750; called by muse, mutect2, varscan2
- POTED | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV55050736; called by mutect2, varscan2
- POTEE | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs747324485, COSV58238683; called by muse, mutect2
- POTEE | c.2670G>A p.M890I | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.138); catalogued as COSV58243998; called by muse, mutect2
- PPIG | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs745414022, COSV99644862; called by muse, mutect2, varscan2
- PPM1D | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as rs773389405, CM137522, COSV59954743; called by muse, mutect2, varscan2
- PPP1R15A | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV52339822; called by muse, mutect2
- PPP2R2B | c.848C>T p.S283L (on ENST00000394409; = p.S349L on NM_181674.2) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770649547, COSV60761342; called by muse, mutect2, varscan2
- PPP2R3C | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145714144, COSV54832924; called by muse, mutect2, varscan2
- PPP3CA | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); catalogued as COSV100548000; called by muse, mutect2, varscan2
- PRAMEF12 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.149); catalogued as COSV100743573; called by muse, mutect2, varscan2
- PRAMEF2 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV99535622; called by muse, mutect2, varscan2
- PRB4 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99686797; called by muse, mutect2
- PRB4 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV54397404, COSV54400933; called by muse, mutect2
- PRDM13 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65030509; called by muse, mutect2, varscan2
- PRDM9 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV99691115; called by muse, mutect2, varscan2
- PRICKLE1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61544341; called by muse, mutect2, varscan2
- PRKAA2 | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100983050; called by muse, mutect2
- PRKCB | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV100335199; called by muse, mutect2, varscan2
- PRKCD | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100388057; called by muse, mutect2, varscan2
- PROS1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs373983977, CM064172, COSV67777518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PROX2 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as COSV71520032; called by muse, mutect2, varscan2
- PRSS1 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100298413; called by muse, varscan2
- PRSS1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs773739445, COSV61195786; called by muse, varscan2
- PRSS35 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601142, COSV63800463; called by muse, mutect2, varscan2
- PRSS36 | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99191322; called by muse, mutect2
- PSG7 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as COSV101343324; called by muse, mutect2, varscan2
- PSMA6 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs1261187716, COSV99809278; called by muse, mutect2, varscan2
- PSMD3 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99228024; called by muse, mutect2, varscan2
- PTPRD | c.4631C>T p.P1544L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV61942853, COSV61995865; called by muse, mutect2, varscan2
- PTPRT | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61957526; called by muse, mutect2, varscan2
- PTPRZ1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1221322432, COSV101100741; called by muse, mutect2, varscan2
- PUM1 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1464558541, COSV99928848; called by muse, mutect2, varscan2
- PVRIG | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1373584292, COSV99444053; called by muse, mutect2, varscan2
- PVRIG | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767318400, COSV99444055; called by muse, mutect2, varscan2
- PXDNL | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1049626878, COSV62493530; called by muse, mutect2, varscan2
- RAB11FIP4 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100365624; called by muse, mutect2, varscan2
- RAD51AP2 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1403466975, COSV67589659; called by muse, mutect2, varscan2
- RANBP10 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100449464; called by muse, mutect2
- RAP1GAP | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV99265792; called by muse, varscan2
- RASAL2 | c.2101C>A p.L701I | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as COSV100862864; called by muse, mutect2, varscan2
- RBAK | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV100806747; called by muse, mutect2, varscan2
- RBM33 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100265683; called by muse, mutect2, varscan2
- RBPJ | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV100623735; called by muse, mutect2, varscan2
- RELB | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1239606493, COSV99673133; called by muse, mutect2, varscan2
- RELN | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as rs759959817, COSV100634716; called by muse, mutect2, varscan2
- RFPL1 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.327); catalogued as COSV100585883; called by muse, mutect2, varscan2
- RFX7 | c.1048C>A p.P350T (on ENST00000559447 / NM_001368074.1; = p.P447T on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100429277; called by muse, mutect2, varscan2
- RGS22 | c.1858C>T p.H620Y | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.255); catalogued as COSV100693708, COSV62668030; called by muse, mutect2, varscan2
- RHOBTB3 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs764271718, COSV101183249; called by muse, mutect2, varscan2
- RIC8B | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750693295, COSV62695446; called by muse, mutect2
- RNASE8 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.657); catalogued as COSV100373538; called by muse, mutect2, varscan2
- RNF148 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100411732, COSV57361663; called by muse, mutect2, varscan2
- RNF148 | c.13A>T p.R5* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | catalogued as COSV100411734; called by muse, mutect2
- RNF150 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100154063; called by muse, varscan2
- RNF213 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs1011062277, COSV100173893; called by muse, mutect2
- RNF5 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100426280; called by muse, mutect2, varscan2
- ROS1 | c.6625C>T p.H2209Y | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63854985; called by muse, mutect2
- RP1 | c.4910G>A p.G1637D | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99608624; called by muse, mutect2, varscan2
- RPL19 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV99841564; called by muse, mutect2
- RPRD2 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV100955331; called by muse, mutect2, varscan2
- RRM2B | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs749882840, COSV52566631; called by muse, mutect2, varscan2
- RSF1 | c.2224C>T p.R742W | Missense Mutation (SNP) | VAF 35/618 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs142580915, COSV57836131; called by muse, mutect2
- RSPH1 | c.258T>G p.D86E | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99370669; called by muse, mutect2, varscan2
- RSPH10B2 | c.648G>A p.W216* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | catalogued as COSV99786371; called by muse, mutect2, varscan2
- RTL6 | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100373860; called by muse, mutect2, varscan2
- RUNDC3B | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV56693132; called by muse, mutect2, varscan2
- SACS | c.7158T>A p.F2386L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV101207676; called by muse, mutect2, varscan2
- SCAPER | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1475146329, COSV100239349; called by muse, mutect2, varscan2
- SCG2 | c.1755G>A p.W585* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as rs768192338, COSV100544885, COSV59541572; called by muse, mutect2, varscan2
- SCML1 | c.452C>T p.P151L (on ENST00000380041 / NM_001037540.3; = p.P124L on NM_006746.6) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101193969, COSV66240973; called by muse, mutect2, varscan2
- SCN11A | c.5141C>T p.A1714V | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs780995821, COSV100182341; called by muse, mutect2, varscan2
- SCN2B | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99635928; called by muse, mutect2, varscan2
- SCN4A | c.5074G>A p.G1692R | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1004360544, COSV101438633; called by muse, mutect2
- SCN8A | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1318533064, COSV61995347; called by muse, mutect2, varscan2
- SEC61A2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV100036616; called by muse, mutect2, varscan2
- SELE | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs777818795, COSV60977871; called by muse, mutect2, varscan2
- SEMA3D | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as rs865954451, COSV99405977, COSV99406563; called by muse, mutect2, varscan2
- SEMG1 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.822); catalogued as COSV99725513; called by muse, mutect2
- SENP1 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV50306876; called by muse, mutect2, varscan2
- SENP1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99137148; called by muse, mutect2, varscan2
- SERPINA7 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as COSV100568323, COSV100568453; called by muse, mutect2, varscan2
- SETD7 | c.691T>A p.F231I | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99918666; called by muse, mutect2, varscan2
- SGCZ | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV101171467; called by muse, mutect2, varscan2
- SH2B1 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100451228; called by muse, mutect2, varscan2
- SHC1 | c.704C>T p.T235I (on ENST00000368445 / NM_183001.5; = p.T125I on NM_003029.5) | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100821152; called by muse, mutect2, varscan2
- SHC2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs755232191, COSV52744999; called by muse, mutect2
- SI | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200745562, COSV52269530; ClinVar: uncertain significance; called by mutect2, varscan2
- SIGLEC1 | c.5036C>T p.S1679L | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs772665418, COSV99170466; called by muse, mutect2, varscan2
- SIGLEC1 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.351); catalogued as COSV99166933, COSV99170470; called by muse, mutect2
- SIGLEC7 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs1157213861, COSV99978890; called by muse, mutect2, varscan2
- SIM1 | c.1786A>G p.N596D | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); catalogued as COSV99492703; called by muse, mutect2, varscan2
- SIRPG | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99403939; called by muse, mutect2, varscan2
- SLC14A2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54912966; called by muse, mutect2, varscan2
- SLC15A2 | c.1729T>C p.F577L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV55197254, COSV99815821; called by muse, mutect2, varscan2
- SLC17A1 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752970228, COSV99766086; called by muse, mutect2, varscan2
- SLC2A10 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100826348; called by muse, mutect2, varscan2
- SLC38A2 | c.417T>A p.Y139* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | catalogued as COSV99874076; called by muse, mutect2, varscan2
- SLC39A5 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as rs1312352809, COSV99907628; called by muse, mutect2, varscan2
- SLC47A2 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1250918964, COSV100328229; called by muse, mutect2, varscan2
- SLC5A7 | c.1137G>A p.W379* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV99887156; called by muse, mutect2, varscan2
- SLC6A3 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54361959; called by muse, mutect2, varscan2
- SLC6A6 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100692452; called by muse, mutect2, varscan2
- SLC8A3 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63524398; called by muse, mutect2, varscan2
- SLC8A3 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV63520732, COSV63524800; called by muse, mutect2, varscan2
- SLFN5 | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs779921381, COSV55483390; called by muse, mutect2, varscan2
- SLITRK3 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1359899576, COSV53845509; called by muse, mutect2, varscan2
- SNCAIP | c.1217G>A p.S406N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99750108; called by muse, mutect2, varscan2
- SNCAIP | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV54403378; called by muse, mutect2, varscan2
- SNTG1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.38); catalogued as COSV99385763; called by muse, mutect2, varscan2
- SNTG1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.956); catalogued as COSV99385766; called by muse, mutect2, varscan2
- SNX33 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV57913107; called by muse, mutect2, varscan2
- SP140 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | catalogued as COSV59448090; called by muse, mutect2, varscan2
- SPAG16 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV100535226; called by muse, mutect2, varscan2
- SPAG16 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1171232370, COSV100535228; called by muse, mutect2
- SPAG17 | c.2521C>T p.H841Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100310306; called by muse, mutect2, varscan2
- SPATA20 | c.1940C>T p.S647F (on ENST00000356488 / NM_001258372.1; = p.S663F on NM_022827.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99136595; called by muse, mutect2
- SPEG | c.6539G>A p.R2180Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs1353097072, COSV100404141; called by muse, mutect2, varscan2
- SPHKAP | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1204426241, COSV100764507; called by muse, mutect2, varscan2
- SPOCK3 | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | catalogued as COSV100693920; called by muse, mutect2, varscan2
- SPTA1 | c.7157C>T p.S2386L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100779076; called by muse, mutect2, varscan2
- SPTA1 | c.6004C>T p.Q2002* | Nonsense Mutation (SNP) | VAF 18/562 reads (3%) | catalogued as COSV100935906; called by muse, mutect2
- SPTA1 | c.5645G>A p.G1882E | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63760853; called by muse, mutect2, varscan2
- SPTBN2 | c.4388C>T p.S1463L | Missense Mutation (SNP) | VAF 110/155 reads (71%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); catalogued as rs768355416, COSV59457167; called by muse, mutect2, varscan2
- SPTBN5 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs753500270, COSV100312090; called by muse, mutect2
- SRRM2 | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.931); catalogued as COSV100071376; called by muse, mutect2, varscan2
- SSR3 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs148305354, COSV54020024; called by mutect2, varscan2
- SSX7 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs782803891, COSV99993753; called by muse, mutect2, varscan2
- ST8SIA5 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 32/192 reads (17%) | PolyPhen benign (0.015); catalogued as rs772209308, COSV59330330; called by muse, mutect2, varscan2
- STAT5A | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs1416364034, COSV61807170; called by muse, mutect2, varscan2
- STK31 | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV100669872; called by muse, mutect2, varscan2
- STPG3 | c.108C>T p.T36= | Splice Region (SNP) | VAF 23/128 reads (18%) | catalogued as COSV100547010; called by muse, mutect2, varscan2
- STX4 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.054); catalogued as COSV58268016; called by muse, mutect2, varscan2
- SUGP1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99895514; called by muse, mutect2
- SYNDIG1L | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100526587; called by muse, mutect2, varscan2
- SYNGR2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99857372; called by muse, mutect2, varscan2
- SYT7 | c.795G>A p.G265= | Splice Region (SNP) | VAF 36/233 reads (15%) | catalogued as COSV99802094; called by muse, mutect2, varscan2
- TANC2 | c.3964C>T p.P1322S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs1228086655, COSV101267653; called by muse, mutect2
- TANC2 | c.3965C>T p.P1322L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1005228380, COSV101267475, COSV101267654; called by muse, mutect2
- TAP1 | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV100841298, COSV62755395; called by muse, mutect2, varscan2
- TAS2R10 | c.550T>A p.F184I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV53701192, COSV99555611; called by muse, mutect2, varscan2
- TBC1D32 | c.3661G>T p.A1221S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV99251103; called by muse, mutect2, varscan2
- TBKBP1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100659224; called by muse, mutect2, varscan2
- TBXT | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs764501069, COSV99752868; called by muse, mutect2, varscan2
- TCF7L2 | c.793G>A p.G265S (on ENST00000355995 / NM_001367943.1; = p.G242S on NM_030756.5) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.258); catalogued as COSV99526605; called by muse, mutect2, varscan2
- TCF7L2 | c.794G>A p.G265D (on ENST00000355995 / NM_001367943.1; = p.G242D on NM_030756.5) | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV99526609; called by muse, mutect2, varscan2
- TCP11L1 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.287); catalogued as rs1203023211, COSV100178347; called by muse, mutect2
- TCP11L1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.813); catalogued as COSV100178348; called by muse, mutect2
- TDRD9 | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs1268553304, COSV59142553; called by muse, mutect2, varscan2
- TDRD9 | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100175542; called by muse, mutect2, varscan2
- TENM1 | c.6721G>A p.A2241T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100950279, COSV100950775; called by muse, mutect2, varscan2
- TENM1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100950590; called by muse, mutect2, varscan2
- TENT5D | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100382884; called by muse, mutect2, varscan2
- TEX101 | c.371G>A p.W124* (on ENST00000598265 / NM_001130011.3; = p.W142* on NM_031451.4) | Nonsense Mutation (SNP) | VAF 39/228 reads (17%) | catalogued as COSV53661775, COSV53663038; called by muse, mutect2, varscan2
- TEX26 | c.560A>G p.Q187R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100994133; called by muse, mutect2, varscan2
- TFAP2D | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.419); catalogued as rs762728199, COSV50445816; called by muse, mutect2, varscan2
- THAP2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs776220464, COSV100350452; called by muse, mutect2, varscan2
- THRAP3 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100663567, COSV63567542; called by muse, mutect2
- THSD7A | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV101448870; called by muse, mutect2, varscan2
- THSD7B | c.4340G>A p.R1447Q (on ENST00000272643; = p.R1445Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs267598902, COSV55651965; called by muse, varscan2
- TIMM17A | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100939019, COSV66171546; called by muse, mutect2, varscan2
- TINAG | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs147898099, COSV99450183; called by muse, mutect2, varscan2
- TINAG | c.713A>T p.K238I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99450673; called by muse, mutect2, varscan2
- TINAGL1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV99593071; called by muse, mutect2, varscan2
- TLL1 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.699); catalogued as COSV50267522, COSV99288889; called by muse, mutect2, varscan2
- TLR5 | c.2177A>G p.N726S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.019); catalogued as rs772519610, COSV100643373; called by mutect2, varscan2
- TLR5 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754140956, COSV100643374; called by muse, mutect2, varscan2
- TMED10 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100339930; called by muse, mutect2, varscan2
- TMEM150C | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV101496955; called by muse, mutect2
- TMEM200A | c.214T>A p.S72T | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV99759944; called by muse, mutect2
- TMEM200A | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51661010; called by muse, mutect2, varscan2
- TMPRSS11A | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs868431518, COSV100602819; called by muse, mutect2, varscan2
- TMPRSS11E | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs371120494; called by muse, mutect2, varscan2
- TMPRSS11F | c.1227G>C p.W409C | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100678781; called by muse, mutect2, varscan2
- TMPRSS9 | c.1348C>T p.R450W (on ENST00000648592; = p.R416W on NM_182973.2) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs755605005, COSV100211684; called by muse, mutect2, varscan2
- TMX1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV100795912; called by muse, mutect2
- TOX | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV63846237; called by muse, mutect2, varscan2
- TRERF1 | c.3437C>T p.P1146L | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100551493; called by muse, mutect2, varscan2
- TRIM15 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100938900; called by muse, mutect2, varscan2
- TRIM23 | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99140190; called by muse, mutect2, varscan2
- TRIM51 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99793099; called by muse, mutect2, varscan2
- TRIO | c.2542C>T p.Q848* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100710289, COSV100710874; called by muse, mutect2, varscan2
- TRPC6 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.048); catalogued as rs750615513, COSV60258416; called by muse, mutect2, varscan2
- TRPC6 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60257579; called by muse, mutect2
- TRPC6 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723746; called by muse, mutect2
- TRPC7 | c.2013G>A p.M671I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1284297074, COSV100725946; called by muse, mutect2
- TRPM4 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV99420778; called by muse, mutect2, varscan2
- TRPV5 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV99520956; called by muse, mutect2, varscan2
- TRRAP | c.2080C>T p.L694F | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100722853; called by muse, mutect2, varscan2
- TSACC | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.61); catalogued as COSV100966227; called by muse, mutect2, varscan2
- TSPAN33 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1186925154, COSV56825449; called by muse, mutect2, varscan2
- TSSK1B | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs762478599, COSV66814892; called by muse, mutect2, varscan2
- TTC3 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs1218020698, COSV100695973; called by muse, mutect2, varscan2
- TTC30A | c.1624C>T p.H542Y | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100826229; called by muse, mutect2, varscan2
- TTC39C | c.1552C>T p.R518C (on ENST00000317571 / NM_001135993.2; = p.R457C on NM_153211.4) | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); catalogued as rs535810615, COSV100455576; called by muse, mutect2, varscan2
- TTN | c.83330C>T p.S27777F (on ENST00000591111; = p.S20353F on NM_003319.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | PolyPhen probably damaging (0.998); catalogued as COSV60421479; called by mutect2, varscan2
- TTN | c.81527G>A p.R27176K (on ENST00000591111; = p.R19752K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | PolyPhen probably damaging (0.987); catalogued as rs770715791, COSV100627010; called by muse, mutect2, varscan2
- TTN | c.62629G>A p.E20877K (on ENST00000591111; = p.E13453K on NM_003319.4) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | PolyPhen benign (0.355); catalogued as rs371063328; called by muse, mutect2, varscan2
- TTN | c.58166C>A p.P19389Q (on ENST00000591111; = p.P11965Q on NM_003319.4) | Missense Mutation (SNP) | VAF 28/244 reads (11%) | PolyPhen probably damaging (0.999); catalogued as rs886042482, COSV100627014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.44551C>T p.P14851S (on ENST00000591111; = p.P7427S on NM_003319.4) | Missense Mutation (SNP) | VAF 32/195 reads (16%) | PolyPhen possibly damaging (0.859); catalogued as COSV100627016; called by muse, mutect2, varscan2
- TTN | c.42590G>A p.R14197Q (on ENST00000591111; = p.R6773Q on NM_003319.4) | Missense Mutation (SNP) | VAF 18/119 reads (15%) | PolyPhen benign (0.007); catalogued as rs199640194; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TTN | c.41251G>A p.E13751K (on ENST00000591111; = p.E6327K on NM_003319.4) | Missense Mutation (SNP) | VAF 26/178 reads (15%) | PolyPhen benign (0.229); catalogued as COSV100627024; called by muse, mutect2, varscan2
- TTN | c.40894G>A p.D13632N (on ENST00000591111; = p.D6208N on NM_003319.4) | Missense Mutation (SNP) | VAF 31/180 reads (17%) | PolyPhen probably damaging (0.998); catalogued as COSV100627028; called by muse, mutect2, varscan2
- TTN | c.38716G>A p.E12906K (on ENST00000591111; = p.E5482K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | PolyPhen benign (0.077); catalogued as rs761539202, COSV59933910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.14636C>T p.P4879L (on ENST00000591111; = p.P3952L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/130 reads (12%) | PolyPhen possibly damaging (0.524); catalogued as rs1441924638, COSV100627036; called by muse, mutect2, varscan2
- TTN | c.14503G>A p.E4835K (on ENST00000591111; = p.E3908K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/224 reads (17%) | PolyPhen possibly damaging (0.737); catalogued as COSV100625408, COSV100627039; called by muse, mutect2, varscan2
- TTN | c.9166C>T p.R3056C (on ENST00000591111; = p.R3010C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | PolyPhen probably damaging (0.998); catalogued as rs377207838; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.8210G>A p.G2737D (on ENST00000591111; = p.G2691D on NM_003319.4) | Missense Mutation (SNP) | VAF 36/188 reads (19%) | PolyPhen probably damaging (1); catalogued as COSV60358869; called by muse, mutect2, varscan2
- UBE2E3 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV101150595; called by muse, mutect2, varscan2
- UGT1A8 | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | catalogued as COSV100990715; called by muse, mutect2, varscan2
- UGT2B11 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs899767353, COSV101485289; called by muse, mutect2, varscan2
- UGT2B28 | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 20/174 reads (11%) | catalogued as COSV100159015; called by muse, varscan2
- UNC79 | c.6660T>A p.F2220L (on ENST00000393151 / NM_001346218.2; = p.F2043L on NM_020818.5) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV99829655; called by muse, mutect2, varscan2
- URB2 | c.1823T>C p.L608P | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99271794; called by muse, mutect2, varscan2
- USP13 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99831540, COSV99831667; called by muse, mutect2, varscan2
- USP17L2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151245022, COSV61556915; called by muse, mutect2, varscan2
- USP20 | c.2049G>A p.R683= | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as rs1450656100, COSV100204698; called by muse, mutect2
- USP38 | c.2405C>T p.S802L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV61025502; called by muse, mutect2, varscan2
- USP54 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1228465967, COSV100161358; called by muse, mutect2, varscan2
- VARS2 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100423057; called by muse, mutect2, varscan2
- VAV1 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs1291265584; called by muse, mutect2
- VAV1 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100408687, COSV58388263; called by muse, mutect2, varscan2
- VPS13B | c.5722C>T p.P1908S | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100663346; called by muse, mutect2
- VPS39 | c.2012C>G p.S671C (on ENST00000348544 / NM_001301138.2; = p.S660C on NM_015289.5) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100529531, COSV58788192; called by muse, mutect2, varscan2
- VWA2 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as rs375532230; called by muse, mutect2
- VWC2L | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs370205207; called by muse, mutect2, varscan2
- VWC2L | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100436273; called by muse, mutect2, varscan2
- WDR48 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.517); catalogued as COSV56531344; called by muse, mutect2, varscan2
- WFDC8 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.039); catalogued as rs373025670, COSV51488520; called by muse, mutect2, varscan2
- WNT3 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV56646555; called by muse, mutect2, varscan2
- WWC1 | c.2218C>T p.H740Y | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.036); catalogued as rs1235484439, COSV99515786; called by muse, mutect2
- XDH | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052440; called by muse, mutect2, varscan2
- XDH | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV101052441; called by muse, mutect2, varscan2
- XKR3 | c.575G>A p.W192* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as rs559105450, COSV100509364; called by muse, mutect2, varscan2
- XKR7 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs778957299, COSV73813534; called by muse, mutect2, varscan2
- XRN1 | c.4751A>C p.Y1584S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); catalogued as COSV99378792; called by muse, mutect2, varscan2
- YIPF5 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178798280, COSV50823110; called by muse, mutect2, varscan2
- ZBED4 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201734469, COSV99351600; called by muse, mutect2, varscan2
- ZBP1 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 35/233 reads (15%) | catalogued as rs1246743662, COSV100473853; called by muse, mutect2, varscan2
- ZBTB38 | c.3301C>T p.Q1101* | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as COSV100375967; called by muse, mutect2, varscan2
- ZC3H13 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV99668806; called by muse, mutect2, varscan2
- ZCCHC9 | c.557G>C p.C186S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99562715; called by muse, mutect2
501 further variants in this file (45 protein-altering or splice-affecting, 427 silent, 29 other) are not listed here.
